Somatic mutation profile of tumor specimen 0DZU0J from CCDI case PBCUGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DZU0J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5e7da98-c3f4-4b2e-ae35-8514a387d4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZU10 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb08bb0d-48fe-4d3c-b66f-5abf613e91de

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM28 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs937561178, COSV56101945; called by muse, mutect2
- DPP10 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs757238978, COSV59678252; called by muse, mutect2
- FAN1 | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs753068609; called by muse, mutect2, varscan2
- KIF13B | c.2776C>G p.H926D | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs771787654, COSV72954513; called by muse, mutect2, varscan2
- LBHD2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs951849156; called by muse, mutect2
- MTTP | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 94/403 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV104376648; called by muse, mutect2, varscan2
- OSR1 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99693772; called by muse, mutect2, varscan2
- PRKAR2B | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs770804316; called by muse, mutect2, varscan2
- SBF2 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs1372841015; called by muse, mutect2
- ULBP2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 107/707 reads (15%) | catalogued as rs201502491; called by muse, mutect2, varscan2
- AXDND1 | c.2721G>T p.E907D | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2
- CHSY3 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- GDF10 | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 98/551 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HAS1 | c.928+2T>A p.X310_splice | Splice Site (SNP) | VAF 70/306 reads (23%) | called by muse, mutect2, varscan2
- LRRK2 | c.5462A>T p.E1821V | Missense Mutation (SNP) | VAF 35/351 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MMP8 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PIK3CG | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 41/714 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- PSME4 | c.5282C>G p.A1761G | Missense Mutation (SNP) | VAF 89/467 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PTPRQ | c.1531C>A p.P511T (on ENST00000616559; = p.P469T on NM_001145026.2) | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPAM1 | c.90T>G p.I30M | Missense Mutation (SNP) | VAF 42/754 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SPTA1 | c.2187del p.H729Qfs*28 | Frame Shift Del (DEL) | VAF 101/689 reads (15%) | called by mutect2, pindel, varscan2
- ABRAXAS2 | c.12C>T p.S4= | Silent (SNP) | VAF 26/447 reads (6%) | catalogued as rs1255570969; called by muse, mutect2
- GATA6 | c.1377C>T p.A459= | Silent (SNP) | VAF 62/254 reads (24%) | catalogued as rs765639422, COSV99333197; called by muse, mutect2, varscan2
- GLB1L3 | c.1344C>T p.S448= | Silent (SNP) | VAF 44/519 reads (8%) | catalogued as rs535333995, COSV68392571; called by muse, mutect2
- NAP1L2 | c.177G>T p.G59= | Silent (SNP) | VAF 174/433 reads (40%) | called by muse, mutect2, varscan2
- NETO1 | c.1524C>T p.H508= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as rs144601570, COSV55007674; called by muse, mutect2, varscan2
- PHF13 | c.216G>A p.A72= | Silent (SNP) | VAF 53/708 reads (7%) | catalogued as rs761732279; called by muse, mutect2
- ZNF827 | c.12G>A p.R4= | Silent (SNP) | VAF 78/320 reads (24%) | catalogued as rs749224779; called by muse, mutect2, varscan2
- BRI3 | c.*90G>T | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- SNAPC4 | c.-50G>A | 5'UTR (SNP) | VAF 76/196 reads (39%) | catalogued as rs1157986945; called by muse, mutect2, varscan2
